Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4G8, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4G8-01A (Primary Tumor).

[page 1 of 2]
Stomach, subtotal gastrectomy :

Advanced gastric carcinoma

(Muc2(-)/Muc5AC(++)/Muc6(-)/CD10(-)/cERB2(-),G type)

1. Location : lower third, center at antrum, lesser curvature

2. Gross type : Borrmann type 2 (ulcerofungating)

3. Histologic type :

tubular adenocarcinoma, poorly differentiated (solid type)(por1)(60%)

>>tubular adenocarcinoma, moderately differentiated (tub2)(40%)

<Addendum>

Final diagnosis: stomach adenocarcinoma, diffuse type.

4. Histologic type by Lauren : diffuse type

5. Growth pattern: expanding growth pattern

6. Size : 8.5x6.5 cm

7. Depth of invasion : invades subserosa (pT3)

8. Resection margin: involved from carcinoma

safety margin: proximal 11.0 cm, distal margin 3750um

9. Lymph node metastasis : metastasis in one out of 64 regional lymph nodes (pN1)

(lesser curvature 0/34 , greater curvature 1/30 , 14V 0/1, #9 0/2, 12P 0/2)

10. Lymphatic invasion : not identified

11. Venous invasion : not identified

12. Perineural invasion : not identified

13. Associated findings : peritumoral lymphocytic infiltration, moderate

intratumoral neutrophilic infiltration, mild

Small intestine, jejunum, resection:

No tumor.

Immunohistochemistry : CD10, MUC2, MUC5ac, MUC6, C-erb B2

ICD-0-3

adenocarcinoma, diffuse type 8145/3

Site: stomach, antrum C16.3

lw 9/27/12

Reviewed (Initials)	Date Reviewed: 9/17/12	

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report that was submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): Stomach adenocarcinoma

Completed By: _____

Diagnostic Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Stomach Adenocarcinoma, Tubular - Diffuse Type	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF	Stomach Adenocarcinoma, Diffuse Type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	According to the original pathology report, this tumor is described as a poorly-differentiated tubular adenocarcinoma. In addendum, we clarified the final diagnosis as an stomach adenocarcinoma, diffuse type.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director: _____

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 276e85f2-6d9f-4341-a41b-27c650021115 (TCGA-HU-A4G8.D42C2BE7-B9F1-4591-ADA6-C28BAE35243A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).